Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A7CZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A7CZ-01A (Primary Tumor).

Last Name:

First Name:

MRN:

Sex: Female Age:

DOB:

Physician:

Location:

ICD 0-3
Paraganglioma, extra-adrenal NOS
8693/1
C-SCF Retroperitoneum C48.0
path Adrenal gland NOS C74.9
W 1/21/14

SURGICAL PATHOLOGY REPORT

Order Number:

Date Received:

Date Completed:

Date Collected:

Diagnosis:

A. Left adrenal gland, excision: Extra-adrenal paraganglioma (two nodules, 1.8 x 1.5 x 1.5 cm and 1.3 x 0.8 x 0.8 cm). Margins negative.

Signing Pathologist:

Comment:

Case seen in consultation with

History:

year-old female with history of pheochromocytoma. Clinical Diagnosis: Pheochromocytoma. Operative Procedure: Laparoscopic adrenalectomy.

Gross Description:

A. "Left adrenal gland"

Received in formalin in a medium container is a procured upon fibrofatty tissue (5.9 x 4.3 x up to 1.5 cm), pre-inked in blue dye. The fat trimmed weight of the adrenal gland is 1.35 grams.

At one end of the gland is a 1.8 x 1.5 x 1.5 cm well-circumscribed solid tan mass. In the middle of the gland is a bicystic 1.3 x 0.8 x 0.8 cm well-encapsulated, well-circumscribed mass filled with a golden tan slightly gelatinous tissue.

Inking code:

The specimen is pre-inked in blue.

Cassette summary:

A1-3. Larger mass.

A4-5. Smaller mass.

Electronically Signed By:

I, the above named pathologist, have personally examined and interpreted the slides from this case.

MRN:

Physician Name:

Last Name:

Report Date/Time:

First Name:

Admit Date:

Page 1 of 2

Source: NCI Genomic Data Commons file 34bc009d-57e3-4ad5-8c4d-012f811853b4 (TCGA-RW-A7CZ.0BD56A2C-B8F2-4BDD-9FEC-2454C1E8CBA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).